Somatic mutation profile of tumor specimen TCGA-UF-A71A-01A (aliquot TCGA-UF-A71A-01A-22D-A34J-08) from TCGA case TCGA-UF-A71A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 67.4 years (24,623 days).
Specimen TCGA-UF-A71A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 071c81cd-45df-4f19-8a71-3e1221668442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A71A-10A (Blood Derived Normal), aliquot TCGA-UF-A71A-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a728eddc-ad7a-45b1-83ae-3267c1d3c8b1

The open-access MAF lists 224 somatic variants for this specimen: 162 protein-altering or splice-affecting, 55 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 55, Nonsense Mutation 8, Splice Site 7, Intron 4, Frame Shift Del 4, RNA 2, Translation Start Site 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDE3A | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs794726868, CM155760, COSV62973682, COSV62977341; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, varscan2
- ADAM19 | c.1258G>T p.G420W | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99978020; called by muse, mutect2, varscan2
- ADAM8 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769225852, COSV101291712; called by muse, varscan2
- ADGRV1 | c.10069A>G p.I3357V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV101316300; called by muse, mutect2, varscan2
- AHNAK | c.16691C>G p.P5564R | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99948896; called by muse, mutect2
- AL592490.1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101308258; called by muse, mutect2, varscan2
- ALX4 | c.1060G>T p.G354W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100241196; called by muse, mutect2, varscan2
- APP | c.1738A>G p.M580V | Missense Mutation (SNP) | VAF 84/139 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs533667466, COSV100696129; called by muse, mutect2, varscan2
- ARHGAP4 | c.1836G>C p.E612D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV100509624; called by muse, mutect2, varscan2
- ASXL3 | c.5618C>T p.P1873L | Missense Mutation (SNP) | VAF 133/258 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99325980; called by muse, mutect2, varscan2
- AXIN1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs36045489, CM043742; called by muse, mutect2, varscan2
- BLZF1 | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100250755; called by muse, mutect2, varscan2
- BNC2 | c.2210C>G p.S737C | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV101034076; called by muse, mutect2
- CASD1 | c.1712A>T p.Q571L | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99802914; called by muse, mutect2, varscan2
- CCDC171 | c.1483A>G p.N495D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV99901561; called by muse, mutect2, varscan2
- CD200R1L | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 155/296 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV101236620; called by muse, mutect2, varscan2
- CDH11 | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.807); catalogued as COSV99219385; called by muse, mutect2, varscan2
- CENPJ | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101121557; called by muse, mutect2, varscan2
- CEP83 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs752784276, COSV100353086, COSV60407618; called by muse, mutect2
- CNTN1 | c.998G>A p.W333* | Nonsense Mutation (SNP) | VAF 18/121 reads (15%) | catalogued as COSV61641766; called by muse, mutect2, varscan2
- COL6A6 | c.4109G>A p.R1370Q | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1285891321, COSV100650703; called by muse, mutect2, varscan2
- CSPG4 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758235057, COSV100414001; called by muse, mutect2, varscan2
- CSRNP1 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99827027; called by muse, mutect2, varscan2
- DENND1B | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs201455013, COSV99345117; called by muse, mutect2, varscan2
- DNAH1 | c.2646G>T p.E882D | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV101326691; called by muse, mutect2, varscan2
- DPRX | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100934112; called by muse, mutect2, varscan2
- DSEL | c.3500T>G p.I1167R | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100025948; called by muse, mutect2, varscan2
- DTWD2 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV100407083; called by muse, mutect2, varscan2
- EFNB3 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs562472485, COSV99872903; called by muse, mutect2, varscan2
- ELOVL2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100675997; called by muse, mutect2, varscan2
- ELP1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65900880; called by muse, mutect2, varscan2
- ESRRG | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1243398576, COSV100753610; called by muse, mutect2, varscan2
- EXOC4 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99554949, COSV99555035; called by muse, mutect2
- F3 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); catalogued as COSV100474379; called by muse, mutect2, varscan2
- FAM189A2 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV99975268; called by muse, mutect2, varscan2
- FANCM | c.5165C>T p.P1722L | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV99951447; called by muse, mutect2, varscan2
- FILIP1L | c.2590C>T p.P864S (on ENST00000354552 / NM_182909.3; = p.P624S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100497223; called by muse, mutect2, varscan2
- FOXB2 | c.177C>A p.N59K | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100942371, COSV65023762; called by muse, mutect2, varscan2
- FRMPD3 | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV99346837; called by muse, mutect2, varscan2
- FSTL5 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100059319; called by muse, mutect2, varscan2
- GABRG1 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99778518; called by muse, varscan2
- GABRP | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267600549, COSV99517011; called by muse, mutect2, varscan2
- GABRR2 | c.1094G>T p.C365F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.723); catalogued as COSV101299012, COSV68764649; called by muse, mutect2, varscan2
- GALNT13 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101223936; called by muse, mutect2, varscan2
- GBP3 | c.1507A>G p.M503V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99352672; called by muse, mutect2
- GLMP | c.898T>C p.C300R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99828042; called by muse, mutect2, varscan2
- GOLGA1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV101001990; called by muse, mutect2, varscan2
- GPALPP1 | c.744T>G p.D248E | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100689248; called by muse, mutect2, varscan2
- GPC5 | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 103/143 reads (72%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); catalogued as COSV100995131; called by muse, mutect2, varscan2
- GRM3 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.061); catalogued as COSV100862733; called by muse, mutect2, varscan2
- GRM3 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.08); catalogued as COSV100862095, COSV64466532, COSV64481485; called by muse, mutect2, varscan2
- GRM5 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553571; called by muse, mutect2
- HGF | c.1456T>A p.S486T | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99738000; called by muse, mutect2, varscan2
- HTR5A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1372976826, COSV55283469; called by muse, mutect2, varscan2
- IFT80 | c.1390T>G p.L464V | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100425013; called by muse, mutect2, varscan2
- IGFL3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV58242939; called by muse, mutect2, varscan2
- IGSF10 | c.1490G>T p.C497F | Missense Mutation (SNP) | VAF 63/363 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1367678417, COSV99191490; called by muse, mutect2, varscan2
- ITM2A | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100964446, COSV100964478; called by muse, mutect2, varscan2
- KBTBD12 | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747694991, COSV100675485; called by muse, varscan2
- KCNJ1 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100131438; called by muse, mutect2, varscan2
- KDM4A | c.1163+2T>C p.X388_splice | Splice Site (SNP) | VAF 150/216 reads (69%) | catalogued as COSV100969588; called by muse, mutect2, varscan2
- KIAA1210 | c.4380T>A p.N1460K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV101274341; called by muse, mutect2, varscan2
- KIAA1549L | c.1882+4C>T | Splice Region (SNP) | VAF 9/103 reads (9%) | catalogued as COSV99684126; called by muse, mutect2
- KIAA2026 | c.4194G>C p.K1398N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.461); catalogued as COSV101199163; called by muse, mutect2, varscan2
- KIF21A | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735574; called by muse, mutect2, varscan2
- KLHL1 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 88/122 reads (72%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV64768090; called by muse, mutect2, varscan2
- KPTN | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as COSV99370224; called by muse, mutect2, varscan2
- KRT5 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99358203; called by muse, mutect2, varscan2
- KRTAP4-1 | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.129); catalogued as rs772650277, COSV100893538, COSV100893580; called by muse, varscan2
- LAMA3 | c.4899G>T p.E1633D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs759564185, COSV99335558; called by muse, mutect2, varscan2
- LAMC1 | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV99280212; called by muse, mutect2, varscan2
- LOXL3 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs748837090, COSV99284164; called by muse, mutect2, varscan2
- LRRC4C | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV53420646, COSV99539155; called by muse, mutect2, varscan2
- LRRTM3 | c.330A>C p.R110S | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100791825; called by muse, mutect2, varscan2
- LTBP2 | c.2618G>T p.S873I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as rs759367257, COSV100000784; called by muse, mutect2, varscan2
- MCM3AP | c.5398C>A p.Q1800K | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99387324; called by muse, mutect2
- MOCS3 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs187280062, COSV54868385; called by muse, mutect2, varscan2
- MRPL46 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs971665839; called by muse, mutect2
- MTMR7 | c.503C>G p.P168R | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99472671; called by muse, mutect2, varscan2
- MYO15A | c.9979A>T p.S3327C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99233910; called by muse, mutect2, varscan2
- NAA25 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 72/187 reads (39%) | catalogued as COSV99927879; called by muse, mutect2, varscan2
- NAGLU | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs368907396; called by muse, mutect2, varscan2
- NDST4 | c.2527del p.R843Efs*22 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as COSV52137800; called by mutect2, pindel, varscan2
- NLRC3 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746010308, COSV57089565; called by muse, varscan2
- OR51M1 | c.394T>C p.F132L | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV100150338, COSV100150423; called by muse, mutect2, varscan2
- OR8D1 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV100766668; called by muse, mutect2, varscan2
- OR8H2 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV100542436, COSV57945167; called by muse, mutect2, varscan2
- PAPPA2 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868658099, COSV100866982; called by muse, mutect2, varscan2
- PLB1 | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100579614; called by muse, mutect2, varscan2
- PLEKHS1 | c.881G>T p.C294F (on ENST00000369310 / NM_182601.1; = p.C300F on NM_024889.5) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.339); catalogued as COSV100613249; called by muse, mutect2, varscan2
- PLXNA4 | c.5062C>A p.L1688M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100326157; called by muse, mutect2, varscan2
- PLXNA4 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV100326159; called by muse, mutect2
- PPP1R9A | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.219); catalogued as COSV99196779; called by muse, mutect2, varscan2
- PRB1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 236/1063 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.253); catalogued as rs760399871, COSV99555994; called by muse, mutect2, varscan2
- PSD4 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as COSV99831351; called by muse, mutect2, varscan2
- PSIP1 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101050984; called by muse, mutect2, varscan2
- PSMF1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 74/561 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850689; called by muse, mutect2, varscan2
- PTGS1 | c.1296+2T>C p.X432_splice | Splice Site (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99793401; called by muse, mutect2, varscan2
- RAB5A | c.328A>T p.R110* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99811124; called by muse, mutect2, varscan2
- RAPGEF2 | c.4274C>T p.P1425L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1448036856, COSV100031488; called by muse, mutect2, varscan2
- RIOK3 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.605); catalogued as COSV100259420; called by muse, mutect2, varscan2
- RNMT | c.605T>G p.L202W | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054805; called by muse, mutect2, varscan2
- RPP30 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99520997; called by muse, varscan2
- RSPH1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV99370629; called by muse, mutect2, varscan2
- RUNDC3B | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV100407203; called by muse, mutect2, varscan2
- SALL3 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101610034; called by muse, mutect2
- SAMD9L | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100561036; called by muse, mutect2, varscan2
- SCAF1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV62183625; called by muse, mutect2, varscan2
- SEMA4D | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100358646; called by muse, mutect2, varscan2
- SERINC3 | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99667927; called by muse, mutect2, varscan2
- SHBG | c.257A>T p.Y86F | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV99352288; called by muse, mutect2
- SI | c.2159+1G>A p.X720_splice | Splice Site (SNP) | VAF 170/354 reads (48%) | catalogued as COSV100016648; called by muse, mutect2, varscan2
- SIAH2 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV57262104, COSV57262820; called by muse, mutect2, varscan2
- SLC9B2 | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 115/232 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV100294243, COSV60020106; called by muse, mutect2, varscan2
- SNW1 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99834487; called by muse, mutect2
- SOX9 | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 80/147 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99818651; called by muse, mutect2, varscan2
- SRRM3 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100418827; called by muse, mutect2, varscan2
- SSC4D | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as rs1317732157, COSV99300104; called by muse, mutect2
- STAT6 | c.2315G>A p.C772Y | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.365); catalogued as COSV55667327; called by muse, mutect2, varscan2
- STEAP4 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112675; called by muse, mutect2, varscan2
- STH | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as COSV99291110; called by muse, mutect2, varscan2
- STK19 | c.290T>A p.L97H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV100514805; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2332T>G p.L778V | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV100562109; called by muse, mutect2, varscan2
- SYNE1 | c.4231C>G p.Q1411E (on ENST00000367255 / NM_182961.4; = p.Q1418E on NM_033071.3) | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1386998081, COSV55006330, COSV99574077; called by muse, mutect2, varscan2
- TAAR1 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs538751400, COSV99257707; called by muse, mutect2, varscan2
- TAS2R3 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093022; called by muse, mutect2, varscan2
- TAS2R41 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1326807276, COSV101281509, COSV101281518; called by muse, mutect2, varscan2
- TENT5D | c.507T>A p.F169L | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100382887; called by muse, mutect2, varscan2
- TFEB | c.804-1G>C p.X268_splice | Splice Site (SNP) | VAF 36/72 reads (50%) | catalogued as COSV100026389; called by muse, mutect2, varscan2
- TMEM107 | c.315G>A p.W105* (on ENST00000437139 / NM_183065.4; = p.W111* on NM_032354.5) | Nonsense Mutation (SNP) | VAF 95/403 reads (24%) | catalogued as COSV100328805; called by muse, mutect2, varscan2
- TMEM131L | c.4607C>T p.S1536F | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866485244, COSV99547910; called by muse, mutect2, varscan2
- TMEM200A | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.451); catalogued as COSV99759733; called by muse, mutect2, varscan2
- TMEM268 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99938783; called by muse, mutect2, varscan2
- TOPORS | c.2183C>G p.A728G | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV100859572; called by muse, mutect2, varscan2
- TRAM1 | c.485+1G>A p.X162_splice | Splice Site (SNP) | VAF 89/207 reads (43%) | catalogued as rs556123107, COSV99140787; called by muse, mutect2, varscan2
- TRAPPC12 | c.657G>T p.L219F | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100160824; called by muse, mutect2
- TRIB2 | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV50230181, COSV99331281; called by muse, mutect2, varscan2
- TSPEAR | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV100554923; called by muse, mutect2, varscan2
- TUBGCP2 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1342653473, COSV99428156; called by muse, mutect2, varscan2
- UAP1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99617938; called by muse, mutect2, varscan2
- VEPH1 | c.442A>T p.M148L | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100747863; called by muse, mutect2, varscan2
- XDH | c.2276G>A p.G759E | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV101052415; called by muse, mutect2, varscan2
- ZBTB39 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100268153; called by muse, varscan2
- ZCRB1 | c.446+1G>C p.X149_splice | Splice Site (SNP) | VAF 26/66 reads (39%) | catalogued as COSV99861338; called by muse, mutect2, varscan2
- ZIC5 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV99940691; called by muse, mutect2, varscan2
- ZNF148 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100642161; called by muse, mutect2, varscan2
- ZNF254 | c.141A>T p.R47S | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100298269; called by muse, mutect2, varscan2
- ZNF331 | c.1312T>A p.S438T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99467724; called by muse, mutect2, varscan2
- ZNF354C | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs374746629; called by muse, mutect2, varscan2
- ZNF415 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99701855, COSV99702169; called by muse, mutect2, varscan2
- ZNF471 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as rs372818781; called by muse, mutect2, varscan2
- ZNF540 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as COSV100329835; called by muse, mutect2
- ZNF606 | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs780776043, COSV58705166; called by muse, mutect2, varscan2
- ZNF91 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100323289; called by muse, mutect2, varscan2
- ZNRF3 | c.1423C>T p.Q475* (on ENST00000544604 / NM_001206998.2; = p.Q375* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV60439498; called by muse, mutect2, varscan2
- CARD6 | c.415_436del p.H139Sfs*49 | Frame Shift Del (DEL) | VAF 34/202 reads (17%) | called by mutect2, pindel
- OR10G8 | c.610del p.I204* | Frame Shift Del (DEL) | VAF 35/163 reads (21%) | called by mutect2, pindel, varscan2
- POLR2A | c.2905A>G p.I969V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- POTEA | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SIDT2 | c.3del p.M1? | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.1671C>T p.T557= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs138310411, COSV99403046; called by muse, mutect2, varscan2
- AHNAK2 | c.14832T>G p.A4944= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100318505; called by muse, mutect2, varscan2
- ALDH1L1 | c.2418C>T p.F806= | Silent (SNP) | VAF 63/435 reads (14%) | catalogued as rs372361618; called by muse, mutect2, varscan2
- ALOX15B | c.900C>T p.T300= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as COSV101205620, COSV101205677; called by muse, mutect2, varscan2
- ANKS1B | c.441C>T p.L147= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs1207457870, COSV61362656; called by muse, mutect2, varscan2
- ANO2 | c.369C>T p.S123= (on ENST00000356134 / NM_001278597.3; = p.S127= on NM_001278596.3) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100501874, COSV59045527; called by muse, mutect2, varscan2
- ANXA2R | c.36T>G p.A12= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV100148707; called by muse, mutect2, varscan2
- ASTE1 | c.1317G>A p.R439= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs758588526, COSV99393942; called by muse, mutect2, varscan2
- BCKDK | c.60C>A p.L20= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99570783; called by muse, mutect2, varscan2
- BROX | c.138G>A p.L46= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as COSV100572299; called by muse, mutect2, varscan2
- CCDC86 | c.30G>T p.R10= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs760505982, COSV57124522; called by muse, mutect2
- CDHR2 | c.2760C>T p.D920= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as rs114350001, COSV56138742; called by muse, mutect2, varscan2
- CIPC | c.279C>T p.V93= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs907191782, COSV100694490; called by muse, mutect2, varscan2
- CYP7B1 | c.573C>A p.I191= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs1245820259, COSV100042553; called by muse, mutect2, varscan2
- DCAF8L1 | c.1494C>A p.T498= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV101491520; called by muse, mutect2, varscan2
- DNAH11 | c.6393G>A p.K2131= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100180170; called by muse, mutect2, varscan2
- DUOXA2 | c.114C>T p.F38= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV99973423; called by muse, mutect2, varscan2
- EHMT1 | c.885C>T p.T295= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100604106; called by muse, mutect2, varscan2
- GCC2 | c.2737C>T p.L913= | Silent (SNP) | VAF 48/252 reads (19%) | catalogued as COSV100565581; called by muse, mutect2, varscan2
- GTF2IRD2 | c.474G>A p.E158= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100736455; called by mutect2, varscan2
- H2AC8 | c.303G>C p.V101= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV55127236, COSV55128019; called by muse, mutect2, varscan2
- H4C5 | c.198G>A p.V66= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as COSV63486077, COSV63486239; called by muse, mutect2, varscan2
- HOXD3 | c.939C>A p.A313= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1406693761, COSV50884788, COSV99980354; called by mutect2, varscan2
- ICA1L | c.15G>A p.G5= | Silent (SNP) | VAF 46/174 reads (26%) | catalogued as rs552339558, COSV100841862; called by muse, mutect2, varscan2
- KRT4 | c.945C>T p.Y315= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as rs778125368, COSV53406546; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRTAP4-1 | c.198C>T p.H66= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs1179636480, COSV100893582; called by muse, varscan2
- LRRC4C | c.1611A>T p.T537= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99539153; called by muse, mutect2
- LRRC7 | c.4302T>C p.Y1434= (on ENST00000651989 / NM_001370785.2; = p.Y1354= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 50/78 reads (64%) | catalogued as COSV99228743; called by muse, mutect2, varscan2
- LYPLAL1 | c.432A>G p.V144= | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as COSV100859717; called by muse, mutect2, varscan2
- MCF2L2 | c.3027C>T p.S1009= | Silent (SNP) | VAF 58/533 reads (11%) | catalogued as COSV100193516; called by muse, mutect2, varscan2
- MED20 | c.78G>A p.R26= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99539945; called by muse, mutect2, varscan2
- MKRN2 | c.652T>C p.L218= | Silent (SNP) | VAF 75/114 reads (66%) | catalogued as rs1385469272, COSV99403363; called by muse, mutect2, varscan2
- MYH6 | c.4680C>A p.I1560= | Silent (SNP) | VAF 30/245 reads (12%) | catalogued as COSV100676453, COSV100676867; called by muse, mutect2, varscan2
- MYO6 | c.996A>G p.E332= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV100889395; called by muse, mutect2, varscan2
- NT5C1B | c.543G>A p.A181= (on ENST00000359846 / NM_001199086.2; = p.A121= on NM_033253.4) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV58394988; called by muse, mutect2, varscan2
- OR10J1 | c.438G>T p.L146= | Silent (SNP) | VAF 107/210 reads (51%) | catalogued as COSV71129495; called by muse, mutect2, varscan2
- PSG1 | c.456C>A p.S152= | Silent (SNP) | VAF 53/378 reads (14%) | catalogued as COSV99741045; called by muse, mutect2, varscan2
- RBPMS | c.72G>C p.R24= | Silent (SNP) | VAF 129/194 reads (66%) | catalogued as COSV55124616; called by muse, mutect2, varscan2
- RCVRN | c.324C>G p.L108= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV99874308; called by muse, mutect2, varscan2
- RNFT1 | c.199T>C p.L67= | Silent (SNP) | VAF 42/131 reads (32%) | catalogued as rs746007285, COSV99994520; called by muse, mutect2, varscan2
- SHBG | c.255T>C p.F85= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as COSV52647925, COSV99352287; called by muse, mutect2
- SLC28A1 | c.1647C>T p.I549= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99723360; called by muse, mutect2, varscan2
- SLF1 | c.2169T>C p.S723= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV99476177; called by muse, mutect2, varscan2
- SNTG2 | c.1260G>A p.T420= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs756213124, COSV57977965; called by muse, mutect2, varscan2
- STRAP | c.612A>G p.R204= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as COSV99214876; called by muse, mutect2, varscan2
- TAS2R3 | c.618C>T p.S206= | Silent (SNP) | VAF 37/170 reads (22%) | catalogued as rs1204721249, COSV99924516; called by muse, mutect2, varscan2
- TMEM116 | c.660G>A p.Q220= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as COSV100702249; called by muse, mutect2, varscan2
- UBE3B | c.114C>T p.A38= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV99784306; called by muse, mutect2, varscan2
- USP13 | c.1041C>T p.L347= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as COSV99831568; called by muse, mutect2
- USP29 | c.1782C>A p.P594= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV99518439; called by muse, mutect2, varscan2
- WDR25 | c.1290C>T p.P430= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100092098; called by muse, mutect2, varscan2
- XKR9 | c.339C>T p.F113= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV68772577, COSV68772947; called by muse, mutect2, varscan2
- ZNF415 | c.1383C>T p.I461= | Silent (SNP) | VAF 65/396 reads (16%) | catalogued as COSV99701850; called by muse, mutect2, varscan2
- ZNF781 | c.546A>G p.S182= | Silent (SNP) | VAF 32/190 reads (17%) | catalogued as COSV100669331; called by muse, mutect2, varscan2
- ZNF804B | c.1662G>A p.L554= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV60848989, COSV60851885; called by muse, mutect2, varscan2
- BCL11A | c.386-6373G>C | Intron (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100186244, COSV59625940; called by muse, mutect2, varscan2
- BIRC8 | n.1472G>A | RNA (SNP) | VAF 39/267 reads (15%) | catalogued as COSV101461353; called by muse, mutect2, varscan2
- GCK | c.*2_*3del | 3'UTR (DEL) | VAF 8/24 reads (33%) | called by pindel, varscan2
- MIR92A1 | n.44A>G | RNA (SNP) | VAF 139/186 reads (75%) | catalogued as rs374040259; called by muse, mutect2, varscan2
- PXN | c.831+2215C>G | Intron (SNP) | VAF 57/137 reads (42%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+3769G>A | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100666780; called by muse, mutect2, varscan2
- SYTL2 | c.1615+1298G>A | Intron (SNP) | VAF 44/146 reads (30%) | catalogued as rs376203930; called by muse, mutect2, varscan2
